Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A1AG, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A1AG-01A (Primary Tumor).

[page 1 of 6]
ICB 0-3

Carcinoma, urothelial, NOS 8120/3

Site code: bladder, NOS C67.9

12/30/10
hw

SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOE

Gender:

M

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service: Urology

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Bladder cancer (SCC); radical cystectomy/bilat PLND

Specimens Submitted:

- 1: SP: Right lymph node of cloquet; Excision
- 2: SP: Left pelvic lymph nodes; Dissection
- 3: SP: Bladder, prostate seminal vesicles; Cystoprostatectomy
- 4: SP: Right pelvic lymph nodes; Dissection
- 5: SP: Right common iliac lymph nodes; Dissection
- 6: SP: Pre-sacral lymph nodes; Dissection
- 7: SP: Node of right fossa Marcelle; Dissection
- 8: SP: Left common iliac lymph nodes; Dissection
- 9: SP: Left pelvic lymph nodes; Dissection
- 10: SP: Right pelvic lymph nodes #2; Biopsy
- 11: SP: Right vas deferens
- 12: SP: Left vas deferens
- 13: SP: Left ureter

DIAGNOSIS:

1. SP: Right lymph node of cloquet; Excision

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

2. SP: Left pelvic lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

3. SP: Bladder, prostate seminal vesicles; Cystoprostatectomy:

Tumor Type:

Invasive urothelial carcinoma with squamous differentiation. The squamous component is extensive and makes up almost the entire invasive component of the tumor

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified. The tumor forms a large mass (10 cm) filling the bladder lumen

Bladder Local Invasion:

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Perivesical soft tissues

Extravesical Tumor Extension:

Ureters uninvolved

Prostatic stroma involved, extensive, with extension into periprostatic soft tissue and surrounding the seminal vesicles bilaterally

Vascular Invasion:

Not identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Prostate:

Other ; extensively involved by carcinoma (squamous cell component)

Seminal Vesicles:

Other ; left seminal vesicle involved by carcinoma (squamous cell component)

Perivesical Lymph Nodes:

LN Not involved 9

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR2 (Periprostatic or periseminal vesicle soft tissue invasion) tissue invasion)

4. SP: Right pelvic lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 4

5. SP: Right common iliac lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 4

6. SP: Pre-sacral lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

7. SP: Node of right fossa Marcelle; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

8. SP: Left common iliac lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 5

9. SP: Left pelvic lymph nodes; Dissection:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

10. SP: Right pelvic lymph nodes #2; Biopsy:

Lymph Node Dissection:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Benign lymph nodes
Number of lymph nodes examined: 1

11. **SP: Right vas deferens; Excision:**
Segment of benign vas deferens
12. **SP: Left vas deferens; Excision:**
Segment of benign vas deferens
13. **SP: Left ureter; Excision:**
Segment of benign ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result Spec	al Stain	Comment
AE1:AE3		
IMM	RECUT	
NEG	CONT	

Gross Description:

1). The specimen is received fresh for intraoperative consultation and labeled, "right lymph node of Cloquet", and consists of 1 lymph node measuring 0.5 x 0.5 x 0.4 cm. Entire specimen is bisected and submitted for frozen diagnosis.
Summary of sections: FSC - frozen section control

2). The specimen is received fresh, labeled "Left pelvic lymph nodes" and consists of three pink tan firm lymph nodes ranging from 1 to 2.5 cm in greatest dimension. All lymph nodes are bisected and entirely submitted.
Summary of sections: BLN - bisected lymph nodes

3). The specimen is received fresh, labeled "bladder, prostate, seminal vesicles". It consists of a cystoprostatectomy specimen measuring 15 cm from superior to inferior, 13 cm laterally and 11 cm from anterior to posterior. The bladder measures 14 x 11 x 10 cm. The prostate measures 3.5 x 3 x 2 cm, the right seminal vesicle measures 2.5 x 2 x 0.8 cm, the right vas deferens measures 7 x 0.3 x 0.3 cm, the left seminal vesicle measures 3 x 2.5 x 0.7 cm and the left vas deferens measures 5.5 x 0.3 x 0.3 cm. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a large white necrotic papillary mass filling the entire bladder cavity. The mass measures 10 x 10 x 9 cm which is grossly situated within the posterior wall, obliterating both left and right orifices and trigone. The left ureter is probe patent measuring up to 0.2 cm in maximum diameter but not the right orifice which cannot be identified. The lesion is sectioned to reveal extension to the inked fat grossly. The remaining bladder mucosa is trabeculated. The prostate is serially sectioned to reveal that the bladder mass involves all quadrants of the prostate, bilateral seminal vesicles. The urethral margin is involved by tumor grossly. The specimen is photographed. TPS is submitted. All possible lymph nodes are submitted. The prostate is entirely submitted.
Summary of sections: UTHM - urethral margin, RUM - right ureter margin, LUM - left ureter margin, L- lesion
LUO - left ureter orifice, LA - left anterior wall, RA - right anterior wall, DOM - dome, RSV - right seminal vesicle
LSV - left seminal vesicle, AP - apex prostate, RM - right mid prostate, LM - left mid prostate, RB - right base prostate
LB - left base prostate, LN - possible lymph nodes, ADDR - additional sections right prostate, ADDL - additional sections left prostate, ADDP - additional sections prostate, ADB - additional sections bladder tumor

4). The specimen is received fresh, labeled "Right pelvic lymph nodes" and consists of four pink tan firm lymph nodes ranging from 0.3 to 2.2 cm in greatest dimension. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

5). The specimen is received fresh, labeled "Right common iliac lymph nodes" and consists of four pink tan firm, fatty lymph nodes ranging from 1.2 to 2 cm in greatest dimension. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

6). The specimen is received fresh, labeled "Presacral lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.3 to 3.2 cm in greatest dimension. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

7). The specimen is received fresh, labeled "Node of right fossa Marcelle" and consists of multiple pink tan firm, fatty lymph nodes ranging from 0.2 to 1.4 cm in greatest dimension. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

8). The specimen is received fresh, labeled "left common iliac lymph nodes, fresh and sterile" and consists of three pink tan firm lymph nodes ranging from 1 to 2.4 cm in greatest dimension. All identified lymph nodes are submitted in three cassettes. Summary of sections: LN - lymph nodes

9). The specimen is received fresh, labeled "left pelvic lymph nodes, fresh and sterile" and consists of multiple pink tan firm lymph nodes ranging from 0.2 to 4.4 cm in greatest dimension. All identified lymph nodes are submitted in eleven cassettes. Summary of sections: LN - lymph nodes, BLN - bisected lymph node, QLN - quadrisected lymph node

10). The specimen is received fresh, labeled "right pelvic lymph nodes #2, fresh and sterile" and consists of a 1 x 0.5 x 0.3 cm single pink tan firm lymph node. The lymph node is entirely submitted in one cassette. Summary of sections: LN - lymph node

11. The specimen is received in formalin labeled, "right vas deferens", and consists of a tubular structure 1.2 cm in length and 0.2 cm in diameter; submitted entirely. Summary of sections: SS-serial section

12. The specimen is received in formalin labeled, "left vas deferens", and consists of a tubular structure 3.5 cm in length and 0.2 cm in diameter; submitted entirely. Summary of sections: SS-serial section

13. The specimen is received in formalin labeled, "left ureter", and consists of a tubular structure 1.4 cm in length and 0.5 cm in diameter. It is serially sectioned to reveal patent lumen; submitted entirely. Summary of sections: SS-serial section

Summary of Sections:

Part 1: SP: Right lymph node of cloquet; Excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Left pelvic lymph nodes; Dissection

Block	Sect. Site	PCs
3	BLN	6

Part 3: SP: Bladder, prostate seminal vesicles; Cystoprostatectomy

Block	Sect. Site	PCs
7	adb	7
7	ADDL	7
5	ADDP	5
5	AD DR	5
1	AP	1
1	DOM	1
6	L	6
1	LA	1
1	LB	1
1	LM	1
3	LN	3
1	LSV	1
1	LUM	1
1	LUO	1

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

1	RA	1
1	RB	1
1	RM	1
1	RSV	1
1	RUM	1
1	UTHM	1

Part 4: SP: Right pelvic lymph nodes; Dissection

Block	Sect. Site	PCs
2	LN	4

Part 5: SP: Right common iliac lymph nodes; Dissection

Block	Sect. Site	PCs
2	LN	4

Part 6: SP: Pre-sacral lymph nodes; Dissection

Block	Sect. Site	PCs
5	LN	15

Part 7: SP: Node of right fossa Marcelle; Dissection

Block	Sect. Site	PCs
2	LN	5

Part 8: SP: Left common iliac lymph nodes; Dissection

Block	Sect. Site	PCs
3	LN	3

Part 9: SP: Left pelvic lymph nodes; Dissection

Block	Sect. Site	PCs
2	BLN	2
5	LN	8
4	QLN	4

Part 10: SP: Right pelvic lymph nodes #2; Biopsy

Block	Sect. Site	PCs
1	LN	1

Part 11: SP: Right vas deferens

Block	Sect. Site	PCs
1	SS	1

Part 12: SP: Left vas deferens

Block	Sect. Site	PCs
1	SS	1

Part 13: SP: Left ureter

Block	Sect. Site	PCs
1	SS	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

- 1) FROZEN SECTION DIAGNOSIS: SP: RIGHT LYMPH NODE OF CLOQUET : BENIGN LYMPH NODE
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file adf4d719-bcc5-408b-b2a2-22cf6c64c55d (TCGA-DK-A1AG.CDF2E5C1-FD42-4703-9803-6C08E2FD48BA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).